Gene-level copy-number profile of tumor specimen ALCH-B1XZ-TTP1-A from ALCHEMIST case ALCH-B1XZ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.8 years (23,310 days).
Specimen ALCH-B1XZ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f51f1ce2-1344-4944-90ff-af76442f32c0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1XZ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/3e7dbb8d-cb25-4e2c-8a0d-de16fd0126e8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 673; copy number 1: 22,666; copy number 2: 31,133; copy number 3: 4,066; copy number 4: 361; copy number 5: 7.

Homozygous deletions (total copy number 0; autosomes only): 149 genes in 38 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:944,203–982,093, 4 genes (within-gene range 0–1): NOC2L, KLHL17, PLEKHN1, PERM1.
- chr1:1,020,120–1,056,118, 2 genes: AGRN, AL645608.5.
- chr1:10,639,241–10,654,333, 1 gene (within-gene range 0–1): AL139423.1.
- chr1:43,525,187–43,623,666, 1 gene: PTPRF.
- chr2:130,830,978–130,836,994, 1 gene (within-gene range 0–2): AC133785.1.
- chr4:2,793,071–2,841,098, 1 gene: SH3BP2.
- chr4:3,463,306–3,501,473, 1 gene: DOK7.
- chr4:4,117,925–4,127,569, 2 genes: AC116562.1, OR7E103P.
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.
- chr5:176,595,802–176,899,346, 10 genes (within-gene range 0–1): GPRIN1, SNCB, MIR4281, EIF4E1B, TSPAN17, AC113391.1, AC113391.2, LINC01574, UNC5A, HK3.
- chr7:128,830,406–128,862,626, 2 genes (within-gene range 0–1): FLNC, FLNC-AS1.
- chr8:22,089,150–22,141,951, 4 genes: FAM160B2, NUDT18, HR, REEP4.
- chr9:34,551,432–34,590,140, 2 genes: CNTFR, CNTFR-AS1.
- chr11:73,376,399–73,397,474, 2 genes: RELT, AP000763.4.
- chr14:100,143,957–100,159,645, 1 gene (within-gene range 0–2): DEGS2.
- chr14:100,537,147–100,589,326, 3 genes: BEGAIN, AL845552.2, AL163974.1.
- chr15:41,828,092–41,894,053, 6 genes (within-gene range 0–1): JMJD7, JMJD7-PLA2G4B, PLA2G4B, SPTBN5, RNA5SP393, MIR4310.
- chr15:74,173,710–74,176,872, 1 gene (within-gene range 0–1): ISLR.
- chr15:75,674,322–75,727,688, 4 genes (within-gene range 0–1): CSPG4, AC105020.4, AC105020.1, ODF3L1.
- chr15:93,035,273–93,089,204, 2 genes: RGMA, YBX2P2.
- chr16:268,301–283,010, 3 genes (within-gene range 0–1): RGS11, Z69667.1, ARHGDIG.
- chr16:14,363,109–14,418,908, 2 genes: LINC02130, AC040173.1.
- chr16:67,109,941–67,227,048, 14 genes: C16orf70, B3GNT9, TRADD, FBXL8, AC074143.1, HSF4, NOL3, KIAA0895L, EXOC3L1, E2F4, ELMO3, MIR328, AC040160.2, LRRC29.
- chr16:70,661,204–70,801,160, 9 genes: MTSS2, AC020763.4, VAC14, AC020763.3, AC020763.1, VAC14-AS1, AC020763.5, AC020763.2, AC027281.1.
- chr16:75,218,988–75,268,053, 4 genes: CTRB1, AC009078.2, BCAR1, AC009078.3.
- chr17:142,789–386,254, 7 genes: DOC2B, LINC02091, RPH3AL, AC129507.4, AC129507.1, AC129507.2, AC129507.3.
- chr17:439,978–511,347, 2 genes (within-gene range 0–1): RFLNB, AC015853.2.
- chr17:523,140–540,576, 1 gene (within-gene range 0–1): AC015853.3.
- chr17:1,934,677–2,043,425, 7 genes: RTN4RL1, AC099684.2, AC099684.1, AC099684.3, AC090617.10, OVCA2, AC090617.3.
- chr17:2,337,498–2,401,104, 5 genes (within-gene range 0–1): SGSM2, AC006435.3, AC006435.2, MNT, AC006435.1.
- chr17:4,433,940–4,608,319, 9 genes: SPNS3, AC127521.1, AC118754.1, SPNS2, MYBBP1A, GGT6, AC118754.2, TXNP4, SMTNL2.
- chr17:17,681,458–17,811,453, 4 genes (within-gene range 0–1): RAI1, RAI1-AS1, SMCR5, AC122129.2.
- chr18:79,395,856–79,529,325, 6 genes (within-gene range 0–1): NFATC1, AC018445.3, AC018445.5, AC018445.1, AC018445.4, AC018445.2.
- chr22:41,301,525–41,360,147, 1 gene: ZC3H7B.
- chr22:43,038,585–43,052,366, 1 gene (within-gene range 0–1): TTLL1-AS1.
- chr22:45,875,932–46,113,928, 16 genes: BX324167.2, BX324167.1, WNT7B, BX537318.2, BX537318.1, LINC00899, PRR34, AL121672.3, PRR34-AS1, MIRLET7BHG, AL121672.1, AL121672.2, MIR3619, MIRLET7A3, MIR4763, MIRLET7B.
- chr22:50,245,183–50,307,646, 4 genes: HDAC10, MAPK12, MAPK11, PLXNB2.
- chr22:50,314,631–50,317,025, 2 genes (within-gene range 0–1): CR559946.1, CR559946.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:44,107,373–44,240,966, 7 genes, copy number 5: PWP2, GATD3A, LINC01678, AP001056.2, AP001056.1, AP001057.1, ICOSLG.

Autosomal genes at a single copy (total copy number 1): 20,341. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
